Gene-level copy-number profile of tumor specimen TCGA-CC-A7II-01A from TCGA case TCGA-CC-A7II, project TCGA-LIHC (Liver Hepatocellular Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Hepatocellular carcinoma, NOS; Tissue or organ of origin: Liver; AJCC pathologic stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 55.0 years (20,079 days).
Specimen TCGA-CC-A7II-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LIHC.95f1918f-ffab-48a7-9ef7-2a5d3f260acf.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CC-A7II-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5e0209f6-26f9-4847-bfb9-6c0caa6f92dd

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 272; copy number 2: 3,344; copy number 3: 6,723; copy number 4: 20,151; copy number 5: 13,735; copy number 6: 9,546; copy number 7: 3,366; copy number 8: 292; copy number 9: 700; copy number 13: 192; copy number 14: 459; copy number 16: 396; copy number 17: 302; copy number 19: 30; copy number 20: 60; copy number 25: 106; copy number 27: 63; copy number 35: 30; copy number 40: 19; copy number 42: 28.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-CC-A7II-01A-11D-A33B-01): tumor purity 0.56, ploidy 4.67, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 2,385 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:21,690,398–22,575,788, 30 genes, copy number 35: GFRA2, OR6R2P, DOK2, XPO7, NPM2, FGF17, DMTN, FAM160B2, NUDT18, HR, REEP4, LGI3, SFTPC, BMP1, AC105206.1, AC105206.3, PHYHIP, MIR320A, POLR3D, AC105206.2, PIWIL2, SLC39A14, AC105910.1, RNU6-336P, PPP3CC, AC087854.1, BTF3P3, SORBS3, AC037459.4, AC037459.3.
- chr8:31,639,222–32,855,666, 1 gene, copy number 42 (within-gene range 4–42): NRG1.
- chr8:32,026,210–43,131,180, 206 genes, copy number 16–42 (within-gene range 4–42) (broad region; genes not listed).
- chr8:98,371,228–98,942,827, 1 gene, copy number 17 (within-gene range 7–17): STK3.
- chr8:98,412,882–145,066,685, 740 genes, copy number 13–17 (broad region; genes not listed).
- chr19:27,638,483–41,207,539, 522 genes, copy number 14–27 (within-gene range 4–27) (broad region; genes not listed).
- chr19:42,297,033–45,873,797, 185 genes, copy number 20–40 (broad region; genes not listed).
- chr20:32,631,625–55,781,231, 565 genes, copy number 9 (broad region; genes not listed).
- chr22:45,875,932–50,801,309, 135 genes, copy number 9 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 262. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
